Gene-level copy-number profile of specimen HCM-SANG-0275-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0275-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0275-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aa00f369-19db-4885-9622-4c56dfaa13dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0275-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/093392e3-5d4f-4cca-9210-8577d95115a7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 519; copy number 1: 880; copy number 2: 35,334; copy number 3: 18,480; copy number 4: 865; copy number 5: 2,781; copy number 6: 2; copy number 7: 46.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr8:12,095,176–12,196,280, 11 genes: DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,829 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 6 (within-gene range 3–6): PRAMEF6, PRAMEF28P.
- chr6:32,659,467–32,668,383, 2 genes, copy number 5: HLA-DQB1, HLA-DQB1-AS1.
- chr8:40,114,651–89,243,793, 711 genes, copy number 5–7 (broad region; genes not listed).
- chr8:90,058,608–141,002,216, 674 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:140,940,562–145,066,685, 188 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–60,653,784, 1,252 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 880. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
